Somatic mutation profile of tumor specimen TCGA-DJ-A2Q0-01A (aliquot TCGA-DJ-A2Q0-01A-11D-A202-08) from TCGA case TCGA-DJ-A2Q0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 57.4 years (20,973 days).
Specimen TCGA-DJ-A2Q0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0af4c931-6ada-40a8-8fa1-a33b1a679b81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q0-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q0-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9be7c106-5078-4294-91d2-296ed87813eb

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 4, In Frame Ins 1, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP36 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1484991750, COSV52269997; called by muse, mutect2, varscan2
- CES5A | c.1126-2A>T p.X376_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as COSV51868921; called by muse, mutect2
- CYP2A13 | c.152C>G p.T51R | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.803); catalogued as COSV57839298; called by muse, mutect2
- DEFB118 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 11/147 reads (7%) | catalogued as rs1378169108, COSV53621156; called by muse, mutect2
- FOXK2 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs902836810, COSV58877757; called by muse, mutect2, varscan2
- GNAL | c.199G>A p.V67I (on ENST00000269162 / NM_001142339.3; = p.V144I on NM_182978.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as COSV52331519; called by muse, mutect2, varscan2
- ICMT | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV59474172; called by mutect2, varscan2
- JAKMIP2 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs373933909, COSV54611275; called by muse, mutect2, varscan2
- LAMA5 | c.9532C>G p.Q3178E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs746309266, COSV53367114, COSV53374403; called by muse, mutect2, varscan2
- PTPRZ1 | c.5017T>G p.L1673V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.189); catalogued as COSV66442402; called by muse, mutect2
- R3HCC1L | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV54403881; called by muse, mutect2, varscan2
- RINT1 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.524); catalogued as COSV57559805; called by muse, mutect2
- RYR2 | c.4469C>A p.A1490E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63679382, COSV63702770; called by muse, mutect2, varscan2
- SLITRK3 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV53845984; called by muse, mutect2, varscan2
- ZNF385D | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55767808; called by muse, mutect2, varscan2
- SPANXB1 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- TACC2 | c.1312_1317dup p.G438_S439dup | In Frame Ins (INS) | VAF 48/142 reads (34%) | called by mutect2, pindel, varscan2
- ADCY8 | c.2613G>T p.L871= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV53919639; called by muse, mutect2, varscan2
- AP1G1 | c.2286C>G p.L762= | Silent (SNP) | VAF 15/344 reads (4%) | catalogued as COSV55493394; called by muse, mutect2
- GOLM2 | c.48C>T p.L16= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as rs372220445, COSV100247859; called by muse, mutect2, varscan2
- MCM3 | c.2319C>T p.I773= (on ENST00000229854 / NM_001366374.2; = p.I763= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 79/221 reads (36%) | catalogued as rs111523955, COSV57717324, COSV57718207; called by muse, mutect2, varscan2
- OR14I1 | c.108G>A p.V36= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs759832591, COSV61200070, COSV61200424; called by muse, mutect2, varscan2
- OTOP2 | c.1026C>A p.V342= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV58882993; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500378 del ATTA | 5'Flank (DEL) | VAF 12/52 reads (23%) | catalogued as rs1417886381; called by mutect2, pindel, varscan2
- MIR133A2 | n.45G>A | RNA (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
